Somatic mutation profile of tumor specimen TCGA-WB-A80Q-01A (aliquot TCGA-WB-A80Q-01A-11D-A35I-08) from TCGA case TCGA-WB-A80Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-WB-A80Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a302d30b-9706-4137-a998-641be5ebda33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A80Q-10A (Blood Derived Normal), aliquot TCGA-WB-A80Q-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fbd5581-a66b-4e1b-a2f1-c37a3a91bc36

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.985A>C p.M329L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV53066306, COSV99260598; called by muse, mutect2, varscan2
- PLCB4 | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1021841547; called by muse, mutect2, varscan2
- RAB40A | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV58490828; called by muse, mutect2, varscan2
- TTPAL | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as COSV52829755; called by muse, mutect2, varscan2
- VWA3B | c.3824C>G p.P1275R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as rs1279441651; called by muse, mutect2, varscan2
- ADAM20 | c.1703A>T p.N568I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FIGN | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KCNJ16 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MGAT2 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NHLRC2 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3G | c.168C>T p.P56= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- GPRIN3 | c.1134C>G p.A378= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.609C>G p.T203= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2
